Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8P8, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8P8-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

ICD O-3
Adenocarcinoma, intestinal
8144/3
Site: Body of stomach
C16.2
4/3/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

1 - "Lymph node chain 11p":

- Absence of neoplasia (0/1).

2 - "Product of subtotal gastrectomy $\frac{3}{4}$ + D2 lymphadenectomy":

- Moderately differentiated adenocarcinoma, intestinal type of Lauren, measuring 3.3 cm in length, infiltrating the wall until the perigastric adipose tissue;

- Angiolymphatic invasion present;

- Perineural invasion present;

- Moderate peritumoral desmoplasia;

- Discrete peritumoral lymphocitary infiltrate;

- Margins uninvolved by neoplasia;

- Non-neoplastic gastric segment exhibiting chronic gastritis with intestinal metaplasia;

- Epiploon segment exhibiting congested mature adipose tissue.

- 12 lymph nodes were dissected in perigastric adipose tissue in the small curvature and 6 in the greater gastric curvature, all uninvolved by neoplasia (0/18).

Primary Site Discrepancy		☒
ICDAA Discrepancy		☒

Source: NCI Genomic Data Commons file 3a89d5c3-0343-4aaf-9f2d-03e263125ddd (TCGA-VQ-A8P8.FBD88F68-2CF0-472A-858F-28E30180A827.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).